Gene-level copy-number profile of tumor specimen ALCH-AFAX-TTP1-A from ALCHEMIST case ALCH-AFAX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.0 years (21,201 days).
Specimen ALCH-AFAX-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6ac28d4c-efe2-4025-8da3-d1efb79a30a4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AFAX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/76153e19-7e05-4517-b7ad-f070ca6cd9fe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,931; copy number 2: 55,599; copy number 3: 118; copy number 4: 75; copy number 5: 90; copy number 6: 67; copy number 7: 28; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 190 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:24,949,163–26,299,290, 31 genes, copy number 5–6 (within-gene range 2–6): AC026310.1, BRI3P2, C12orf77, IRAG2, CENPUP2, AC023510.1, AC023510.2, CFAP94, ETFRF1, KRAS, AC092794.1, AC092794.2, AC087239.1, RNU4-67P, AC092451.1, LMNTD1, AC092451.2, FAM133GP, TUBB4BP1, AC022367.1, RN7SKP262, AC019209.3, TDGP1, AC019209.2, AC019209.1, RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5.
- chr12:28,821,975–29,784,759, 14 genes, copy number 7 (within-gene range 4–7): AC022081.1, AC024255.1, AC012150.1, FAR2, AC012150.2, AC009318.4, AC009318.1, AC009318.3, AC009318.2, ERGIC2, OVCH1-AS1, OVCH1, TMTC1, AC009320.1.
- chr12:31,280,422–32,646,050, 47 genes, copy number 5–6: AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6, DENND5B, RNU6-618P, AC068792.1, AC022080.1, AC022080.2, Y_RNA, ANKRD49P2, DENND5B-AS1, RNU5F-4P, RPL31P50, AK4P3, AC068774.1, ETFBKMT, AMN1, STMN1P1, AC023157.2, AC023157.1, IFITM3P2, H3-5, RNU6-1069P, AC023050.2, AC023050.3, LINC02422, AC023050.4, AC023050.1, RPL12P32, AC023050.5, RESF1, AC016957.2, AC016957.1, AC048344.2, AC048344.3, AC048344.1, BICD1, AC048344.4, AC016954.1, AC026356.1, AC026356.2, Y_RNA, FGD4, RNU6-494P.
- chr12:57,723,761–57,984,761, 25 genes, copy number 5–8: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2.
- chr12:65,278,643–65,491,430, 1 gene, copy number 6 (within-gene range 3–6): MSRB3.
- chr12:65,418,731–66,066,338, 15 genes, copy number 5–6: KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362.
- chr12:67,989,445–68,234,686, 1 gene, copy number 6 (within-gene range 3–6): IFNG-AS1.
- chr12:68,035,767–68,576,136, 13 genes, copy number 6: HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP.
- chr12:68,674,371–68,971,570, 14 genes, copy number 7: AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,239,569–70,443,923, 29 genes, copy number 5: CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P.

Autosomal genes at a single copy (total copy number 1): 75. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
